Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHA, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAHA-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 6,5 cm; no angio-invasion; no invasion in rete-testis; no invasion of tunica albuginea; surgical margin spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD O 3
Seminoma NOS 9061/3
Site L Testis NOS C62.9
9/3/7/14

Source: NCI Genomic Data Commons file 5be5f83d-07d8-43e1-b9c2-7558c687db60 (TCGA-2G-AAHA.80F53486-6C45-4E82-BA51-3E55AB0B6D8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).